TCGA case TCGA-61-2113 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/71faa2c1-0d5b-4dcc-bdf9-f2405f29907c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Dead; Days to death: 676 days (1.9 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 54.0 years (19,722 days); Year of diagnosis: 1999; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 143 days; Number of cycles: 6; Treatment dose: 4,026 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 143 days; Number of cycles: 6; Treatment dose: 1,480 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 336 days; Days to treatment end: 392 days (1.1 years); Number of cycles: 2; Treatment dose: 418 mg/m2; Route of administration: Intraperitoneal / Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 54.8 years (20,013 days); Days to diagnosis: 291 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 291 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 291 days.
- Follow-up contact recording only the day: day 676.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-61-2113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.6; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-61-2113-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30.
  Slide TCGA-61-2113-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30.
- Sample TCGA-61-2113-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; History neoadjuvant treatment: No; Anatomic organ subdivision: Right; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 2, Route of administrations: Route of administration: IP; Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 676 days; disease-specific survival: event status not recorded, 676 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 291 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-61-2113-01A-01D-0663-01): tumor purity 0.49, ploidy 4.63, whole-genome doublings 2.
